Somatic mutation profile of tumor specimen BA2147D (aliquot aq-BA2147D) from BEATAML1.0 case 2388, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.8 years (25,506 days).
Specimen BA2147D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0639e2f6-2b09-4847-9072-54ea096eef3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2719D (Solid Tissue Normal), aliquot aq-BA2719D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae328083-649e-46f3-bf88-b3266d93b1c8

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITIH5 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1159248266, COSV56912714; called by mutect2, varscan2
- VPS13A | c.4104C>G p.H1368Q | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62425288; called by muse, mutect2
- ZNF398 | c.287G>C p.W96S | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60066523; called by muse, mutect2
- ZNF423 | c.253G>A p.E85K (on ENST00000563137 / NM_001379286.1; = p.E77K on NM_015069.4) | Missense Mutation (SNP) | VAF 32/298 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.525); catalogued as rs1413346530, COSV52205888; called by muse, mutect2, varscan2
- FOXD4L4 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BCL11B | c.2283C>T p.D761= (on ENST00000357195 / NM_001282237.2; = p.D690= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/83 reads (48%) | catalogued as rs1022551537; called by muse, mutect2, varscan2
- CHST8 | c.294G>A p.P98= | Silent (SNP) | VAF 44/85 reads (52%) | catalogued as rs750673635, COSV99381469; called by muse, varscan2
- KCNA6 | c.945G>C p.L315= | Silent (SNP) | VAF 16/107 reads (15%) | called by muse, mutect2, varscan2
